Surgical pathology report (de-identified scan), TCGA case TCGA-TS-A8AI, project TCGA-MESO (Mesothelioma), tissue source site University of Pennsylvania, specimen TCGA-TS-A8AI-01A (Primary Tumor).

[page 1 of 4]
Age: [REDACTED] years Sex: Male

Date Printed:
Date Collected :
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

Surgical Pathology Report

Clinical Information

year old male patient with history of mesothelioma presents for PDT and radical pleurectomy.

Final Diagnosis

1. PREVIOUS INCISION SITE:

Skin and underlying soft tissue with focal presence of malignant mesothelioma, epithelial type.
Suture granuloma and chronic inflammation present.

2. LEFT RIB:

Portion of rib with bone marrow; no tumor seen.

3. HILAR NODE:

Fibroadipose tissue with presence of malignant mesothelioma, epithelial type.

4. PHRENIC NODE:

One lymph node with focal presence of metastatic malignant mesothelioma.

5. MAMMARY:

Fragments of fibroadipose tissue with focal presence of malignant mesothelioma, epithelial type.
Fragments of vessel wall, no tumor seen.

6. SUBCLAVIAN LYMPH NODE:

Fibroadipose tissue and blood clot with presence of biphasic malignant mesothelioma, predominantly epithelial component.

7. RADICAL PLEURECTOMY:

Biphasic malignant mesothelioma containing both epithelial and sarcomatous components, predominantly epithelial component.

Adherent alveolar lung tissue, focally and superficially invaded by tumor.

Tumor focally invades into the skeletal muscle.

Lymphovascular invasion is present

Foreign body granuloma present.

8. PERICARDIUM:

Fragment of fibroadipose tissue, no tumor seen.

9. 1ST BIOPSY SITE:

Fragments of fibroadipose tissue and skeletal muscle with focal presence of biphasic malignant mesothelioma, predominantly epithelial component.

CGCF ICD-O 3
Mesothelioma, epithelial, malignant 9052/3
path
Mesothelioma, biphasic, malignant- 9053/3
Site: Pleura-NOS C38.4
9/5/27/14

Name: [REDACTED]

MR [REDACTED]

[page 2 of 4]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected :
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Skeletal muscle is not involved by the tumor.

10. SECOND BIOPSY SITE:

Skin and underlying soft tissue with presence of biphasic malignant mesothelioma, predominantly epithelial component.
Tumor invades into the skeletal muscle.
Perineural invasion is present.

11. THIRD BIOPSY SITE:

Skin and underlying soft tissue with presence of biphasic malignant mesothelioma, predominantly epithelial component.

12. LEVEL 8:

Fibroadipose tissue with presence of biphasic malignant mesothelioma, predominantly epithelial component.

13. LEVEL 7:

Fragments of lymph nodes with focal presence of metastatic malignant mesothelioma.

The case material was reviewed and the report verified by:

(Electronic signature)

Verification Date:

Frozen Section Diagnosis

FS-1: Previous incision site: Malignant tumor present consistent with mesothelioma.

FS-2: Pericardium: Pericardium with few clusters of entrapped mesothelial cells with no invasive pattern. Defer.

Gross Description

The specimen is received in 14 parts in a container labeled with the patient's name and medical record number.

Specimen #1 is received fresh for frozen section and designated "previous incision site". The specimen consists of multiple yellow tan white firm tissue fragments ranging from 1.0 to 2.0 cm in greatest dimension. The specimen is submitted entirely in three cassettes labeled as 1AFS1.

The remaining sections are submitted in two cassettes, 1B and 1C.

Name: [REDACTED]

MRN: [REDACTED]

[page 3 of 4]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected :
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Specimen #2 is received in formalin and designated "left rib" and consists of three portions of rib measuring 7.0 x 1.5 x 0.6 cm and 8.0 x 1.2 x 0.8 cm and 4.0 x 1.5 x 1.0 cm respectively. The surface of the rib has minimal amount of attached red tan soft tissue. The specimen is entirely decalcified and representative sections are submitted in one cassette labeled 2A.

Specimen #3 is received in formalin and designated "hilar node" and consists of red black anthracotic tissue measuring 2.0 x 2.0 x 0.3 cm. The specimen is submitted entirely in cassette labeled 3A.

Specimen #4 is received in formalin and designated "phrenic node" and consists of one pink tan firm tissue fragment measuring 0.8 x 1.0 x 0.3 cm. The specimen is submitted entirely in one cassette labeled 4A.

Specimen #5 is received in formalin and designated "mammary" and consists of portion of vessel with two smaller branches measuring 3.5 cm in length and 0.8 cm in diameter with two branches, each measuring 6.0 cm in length and 0.2 cm in diameter. The vessels have minimal amount of attached yellow tan lobulated adipose connective tissue parenchyma. The specimen is serially sectioned and representative sections are submitted in one cassette labeled 5A.

Specimen #6 is received in formalin and designated "subclavian lymph node" and consists of two pink tan yellow firm lymph nodes measuring 1.5 x 1.0 x 0.3 cm and 1.0 x 0.4 x 0.2 cm respectively. The specimen is submitted entirely in one cassette labeled 6A.

Specimen #7 is designated "radical pleurectomy" and consists of radical pleurectomy with dome shaped configuration measuring 22.0 x 16.0 x 8.0 cm and the pleural thickness averages from 0.4 to 1.8 cm in thickness. There is also identifiable portion of diaphragm with minimal amount of attached red tan muscle and yellow lobulated adipose tissue. The inner lining of the pleura is white tan shaggy with multiple adhesions. The specimen is serially sectioned disclosing white yellow parenchyma. Also there is a separate piece of pleura measuring 12.0 x 8.0 x 0.8 cm and upon cross sectioning disclosing red tan pink yellow interdigitating parenchyma. Representative sections of the specimen are submitted in 10 cassettes labeled 7A through 7J.

Specimen #8 is designated "pericardium" and consists of previously frozen section of pink tan green membranous tissue fragment measuring 1.2 x 0.2 x 0.1 cm. The specimen is submitted entirely in one cassette labeled 8AFS2.

Specimen #9 is designated "first biopsy site" and consists of one red tan irregular firm connective tissue and muscle fragment measuring 2.5 x 1.0 x 0.6 cm. The specimen is serially sectioned and submitted entirely in one cassette labeled 9A.

Specimen #10 is designated "second biopsy site" and consists of multiple yellow tan firm red muscle and connective adipose tissue fragment, in aggregate, measuring 6.0 x 4.0 x 2.5 cm. The specimen is serially sectioned and representative sections are submitted in five cassettes labeled 10A through 10E.

Specimen #11 is designated "third biopsy site" and consists of two red tan yellow tissue fragments, the largest measuring 5.0 x 4.0 x 2.5 cm with small portion of white tan skin and healed scar measuring 1.5 cm in length. The specimen is serially sectioned and representative sections are submitted in four cassettes labeled 11A through 11D.

Name: [REDACTED]
MRN: [REDACTED]

[page 4 of 4]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected :
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Specimen #12 is designated "level 8" and consists of one brown red firm tissue fragment measuring 2.0 x 1.0 x 0.3 cm. The specimen is submitted entirely in one cassette labeled 12A.

Specimen #13 is designated "level 7" and consists of multiple red tan black anthracotic tissue fragments ranging from 0.3 to 2.0 cm in greatest dimension. The specimen is submitted entirely in two cassettes labeled 13A and 13B.

Case reviewed with attending pathologist.

Dictation by:

Dictated by:

Pathologist(s)

(Prior bx only)

Name: [REDACTED]

MRN: [REDACTED]

Page 4 of 4

Source: NCI Genomic Data Commons file f676e687-1fd0-49e7-900c-a3c66fb63987 (TCGA-TS-A8AI.3D48DFF8-B505-478C-B90B-28015E22B38D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).